Surgical pathology report (de-identified scan), TCGA case TCGA-LB-A9Q5, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Candler, specimen TCGA-LB-A9Q5-01A (Primary Tumor).

[page 1 of 4]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 1

PATIENT: [REDACTED] ACCT #: [REDACTED] LOC: [REDACTED]
AGE/SX: [REDACTED] ROOM: [REDACTED]
REG DR: [REDACTED] DOB: [REDACTED] BED: [REDACTED]
STATUS: [REDACTED]

SPEC #: [REDACTED] RECD: [REDACTED] STATUS: [REDACTED] PERFORMED AT [REDACTED]
COLL: [REDACTED] TIME IN FORMALIN: 3:42 hrs.
COLD ISCHEMIA TIME: 0:00 mins.

CLINICAL INFORMATION:

Pre-Op Diagnosis: Periampullary carcinoma
Remarks: Tissue banking, stitch marks pancreatic margin
Specimen(s): A. Pancreatic margin
B. Common duct margin
C. Whipple contents
D. Peripancreatic node

MICROSCOPIC DIAGNOSIS

- A. PANCREATIC MARGIN:
- PANCREATIC INTRAEPITHELIAL NEOPLASIA GRADE 1 (PanIN1)
- NEGATIVE FOR CARCINOMA
- B. COMMON DUCT MARGIN:
- INFLAMMATION AND REACTIVE GLANDULAR EPITHELIUM
- NEGATIVE FOR CARCINOMA
- C. WHIPPLE RESECTION:
- POORLY DIFFERENTIATED PANCREATICO-BILIARY ADENOCARCINOMA MEASURING APPROXIMATELY 3 CM
- TUMOR INVADES DUODENAL WALL, AMPULLA, AND PERIPANCREATIC SOFT TISSUE WITH PERINEURAL AND LYMPHATIC INVASION NOTED
- TWO (2) OF (5) FIVE PERIPANCREATIC LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA WITH EXTRANODAL CAPSULAR EXTENSION PRESENT
- SIX (6) LESSER CURVATURE LYMPH NODES NEGATIVE FOR CARCINOMA
- MARGINS NEGATIVE WITH CLOSEST MARGIN RETROPERITONEAL/UNCINATE (4 MM)
- D. TISSUE SUBMITTED AS PERIPANCREATIC LYMPH NODE:
- ONE (1) LYMPH NODE POSITIVE FOR METASTATIC ADENOCARCINOMA

ICD-O 3
Adenocarcinoma, duct NOS 8500/3
Site: Pancreas head C25.0
QW 4/3/14

COMMENT(S)

The sections demonstrate a poorly differentiated adenocarcinoma involving the head of pancreas and ampullary region extending into the duodenal wall without duodenal mucosal involvement. Based on the overall morphologic findings, the carcinoma is best classified as arising from the pancreaticobiliary tract rather than from the ampulla. This distinction, however, can be somewhat problematic in tumors involving both regions. This tumor does demonstrate extraprostatic extension as well as vascular and perineural

*** CONTINUED ON NEXT PAGE **

[page 2 of 4]
RUN DATE:
RUN TIME:
RUN USER:

Specimen Inquiry
Lab Database:

PAGE 2

SPEC #: PATIENT: (Continued)

COMMENT(S) (Continued)

invasion with regional lymph node metastasis. Immunohistochemical stains performed on the tumor with appropriate control reveal the following immunoprofile: CK7 and CA19-9 positive; CK20 and CDX2 negative.

COLLEGE OF AMERICAN PATHOLOGISTS' PROTOCOL FOR EXAMINATION OF SPECIMENS WITH CARCINOMA OF THE EXOCRINE PANCREAS, BASED ON AJCC/UICC TNM, 7TH EDITION

Specimen:	Head of pancreas, duodenum, stomach, common bile duct
Procedure:	Pancreaticoduodenectomy
Tumor Site:	Pancreatic head
Tumor Size:	3 cm in greatest dimension
Histologic Type:	Ductal adenocarcinoma
Histologic Grade:	G3: poorly differentiated
Microscopic Tumor Extension:	Tumor invades ampulla of Vater or sphincter of Oddi; tumor invades duodenal wall; tumor invades peripancreatic soft tissues
Margins:	Margins uninvolved by invasive carcinoma Distance of invasive carcinoma from closest margin: 4 mm
Treatment Effect:	No prior treatment
Lymph-Vascular Invasion:	Present
Perineural Invasion:	Present
Pathologic Staging:	Primary Tumor: pT3 Regional Lymph Nodes: pN1 Number examined: 12 Number involved: 3 Distant Metastasis: Not applicable

GROSS DESCRIPTION:

A. Received fresh for frozen section labeled with the patient's name and "pancreatic margin" is a 2 x 2 x 0.5 cm portion of pancreas. A stitch marks the true margin. The specimen is submitted in block A for frozen section of the margin.

B. Received fresh for frozen section labeled with the patient's name and "common bile duct margin" is the common bile duct margin consisting of two dilated ducts, one measuring 1.5 cm and an adjacent smaller duct measuring 0.8 cm. A suture marks the true margin. Blue ink is applied to the true margin. The specimen is submitted en face in block B for frozen section.

C. Received fresh in the operating room labeled with the patient's name and "whipple contents" with request for tissue banking is a whipple resection. The following measurements are obtained: length across from the lesser curvature 10 cm, length along greater curvature 9 cm, proximal gastric margins 7 cm, duodenum 13 cm in length and 3 cm in diameter, common bile duct 1 cm in length, 1.5 cm in diameter at margin, and pancreatic head approximately 5.5 x 5 x 4 cm. There is a posterior-inferior staple line which measures 4.5 cm in length. Adjacent to this is a stitch which marks the uncinate/retroperitoneal margin. Yellow ink is applied to this margin. The pancreatic

** CONTINUED ON NEXT PAGE **

[page 3 of 4]
RUN DATE:
RUN TIME:
RUN USER:

Specimen Inquiry
Lab Database:

PAGE 3

SPEC #: PATIENT: (Continued)

GROSS DESCRIPTION: (Continued)

margin measures 2 x 1.5 cm. Blue ink is applied to this margin. There is a stent within the common bile duct. Black ink is applied to the common bile duct margin. Black ink is also applied along the stapled gastric margin and blue ink is applied along the stapled duodenal margin. The adipose tissue adjacent to the lesser and greater curvature are separated for lymph node dissection. The specimen is opened lengthwise along the lesser curvature and along the border of the duodenum. The mucosa surrounding the ampulla of Vater is heaped up and hyperemic for three-fourths of the circumference. I am hesitant to completely open the specimen in the fresh state as that this may represent an ampullary or periampullary area tumor which would require better fixation. In an attempt to see if there is a pancreatic head mass, I placed an incision along the posterior aspect of the pancreas going into the head of the pancreas revealing a possible tumor within the pancreatic head where the pancreatic tissue has a more gray-white appearance and fibrotic texture. Within the plane of section, this area measures approximately 1.5 cm. A small portion of this area is provided to the tissue bank coordinator. The specimen is then pinned out on corkboard and placed into formalin for overnite fixation prior to further sectioning and evaluation. Blue ink is further applied to the staple line adjacent to the uncinate process.

The fixed specimen is evaluated. A longitudinal cut is made from the ampulla of Vater through to the common bile duct margin. In this plane, a tumor is identified in the periampullary region from the ampulla of Vater extending for 2.3 cm. The tumor tapers at the junction of the common bile duct and pancreatic duct. This area is contiguous with the area in the pancreatic head identified at the time of initial evaluation for tissue banking and the mass is judged to measure approximately 3 cm. Several peripancreatic lymph nodes are identified which range from 0.8 to 1.5 cm. Several lymph nodes are identified along the lesser curvature ranging up to 1 cm.

Cassette Summary:

- C1 - common bile duct margin of this specimen
- C2 - pancreatic margin of this specimen
- C3 - longitudinal section through ampulla of Vater
- C4,5 - perpendicular sections through ampulla of Vater
- C6,7 - sections adjacent to retroperitoneal (uncinate) margin
- C8-10- additional sections of tumor
- C11,12- peripancreatic lymph nodes with two lymph nodes present in C12 bisected, one inked
- C13,14- lesser curvature lymph nodes
- C15 - gastric margin
- C16 - pylorus
- C17 - small bowel margin

D. Received fresh labeled with the patient's name and peripancreatic node is a 2 x 1.3 x 0.5 cm tan lymph node bisected and submitted in block D.

INTRAOPERATIVE CONSULTATION:
FROZEN SECTION DIAGNOSIS:

A. PANCREATIC MARGIN:

** CONTINUED ON NEXT PAGE **

[page 4 of 4]
RUN DATE:
RUN TIME:
RUN USER:

Specimen Inquiry
Lab Database:

PAGE 4

SPEC #:

PATIENT:

(Continued)

INTRAOPERATIVE CONSULTATION: (Continued)

- NEGATIVE FOR INVASIVE CARCINOMA WITH PANCREATIC INTRADUCTAL NEOPLASIA GRADE 1 IDENTIFIED

B. COMMON BILE DUCT MARGIN:

- INFLAMMATION, FIBROSIS, REACTIVE GLANDULAR EPITHELIUM AND FOCAL ATYPICAL GLANDULAR EPITHELIUM WITH NO OBVIOUS INVASIVE CARCINOMA IDENTIFIED

Results given to Dr. [REDACTED] in the operating room at

C. GROSS INTRAOPERATIVE EVALUATION:

- FIBROTIC MASS PRESENT IN HEAD OF PANCREAS ADJACENT TO UNCINATE PROCESS ON PARTIAL DISSECTION WITH TISSUE PROVIDED TO TISSUE BANK COORDINATOR
- GROSS MARGINS APPEAR FREE OF INVOLVEMENT
- FINDINGS DISCUSSED WITH DR. [REDACTED] IN THE OPERATING ROOM AT

Signed ____ (signature on file) ____

** END OF REPORT **

Case is (circled) QUALIFIED		

Source: NCI Genomic Data Commons file 0fff318d-e948-4ec9-b405-489545f14a0a (TCGA-LB-A9Q5.54BFFF2A-842D-4207-9753-32DCC2DE15C8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).